Somatic mutation profile of tumor specimen 44a9e976-f859-4a0d-9f4f-70b95b (aliquot 44a9e976-f859-4a0d-9f4f-70b95b_D6) from CPTAC case 26OV011, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 44a9e976-f859-4a0d-9f4f-70b95b: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 451a0ec8-9580-4359-8e4b-9ad1aa33ecad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 94fc93b5-c989-42a0-b139-8d1f92 (Blood Derived Normal), aliquot 94fc93b5-c989-42a0-b139-8d1f92_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63799816-e003-4487-9895-5c7e9c701a7b

The open-access MAF lists 107 somatic variants for this specimen: 76 protein-altering or splice-affecting, 21 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 21, 5'UTR 3, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 2, RNA 2, 3'UTR 2, Intron 2, 3'Flank 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 168/346 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AIFM1 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 55/270 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as rs750418813, COSV54852416; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CELSR2 | c.5932C>T p.R1978* | Nonsense Mutation (SNP) | VAF 20/236 reads (8%) | catalogued as rs1042587630; called by muse, mutect2
- CSPP1 | c.1193C>A p.S398Y (on ENST00000676605; = p.S357Y on NM_024790.6) | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs374330054; called by muse, mutect2, varscan2
- FAM50A | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs372492057; called by muse, mutect2, varscan2
- FOXD4L3 | c.653C>A p.P218H | Missense Mutation (SNP) | VAF 260/815 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as rs1327826886; called by muse, mutect2, varscan2
- IGLV7-43 | c.155A>T p.Y52F | Missense Mutation (SNP) | VAF 158/501 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs186768009; called by muse, mutect2, varscan2
- IRF6 | c.1198C>G p.R400G | Missense Mutation (SNP) | VAF 365/598 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM032593; called by muse, mutect2, varscan2
- KCTD8 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as rs778853493; called by muse, varscan2
- KRT77 | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 70/313 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100527189; called by muse, mutect2, varscan2
- LAD1 | c.1526C>G p.S509C | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.634); catalogued as COSV66212283; called by muse, mutect2
- LRCH3 | c.1844G>A p.R615Q | Missense Mutation (SNP) | VAF 67/112 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs765671495, COSV100605070; called by muse, mutect2, varscan2
- LRRC53 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760861475, COSV53951321; called by muse, mutect2, varscan2
- MARF1 | c.4739C>T p.S1580L | Missense Mutation (SNP) | VAF 104/307 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs773950522, COSV60026027; called by muse, mutect2, varscan2
- MROH2B | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as rs867084467, COSV68189387; called by muse, mutect2, varscan2
- OR5B12 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 124/445 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as rs765663557, COSV56906820; called by muse, mutect2, varscan2
- PLG | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 81/265 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99804220; called by muse, mutect2, varscan2
- PRR11 | c.453G>T p.M151I | Missense Mutation (SNP) | VAF 115/195 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99231543; called by muse, mutect2, varscan2
- ROR2 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 138/471 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs1428165900; called by mutect2, varscan2
- SLIT3 | c.2468G>A p.R823Q | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs780917955; called by muse, mutect2
- TRAF6 | c.67A>G p.M23V | Missense Mutation (SNP) | VAF 113/244 reads (46%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs747559755; called by muse, mutect2, varscan2
- USP21 | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs1245839165; called by muse, mutect2
- VCAN | c.868G>C p.G290R | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764098299, COSV54103833; called by muse, mutect2
- WDFY4 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 105/410 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs147299795; called by muse, mutect2, varscan2
- ADAMTS2 | c.1776-2_1797del p.X592_splice | Splice Site (DEL) | VAF 47/581 reads (8%) | called by mutect2, pindel
- BOD1L1 | c.8293G>C p.E2765Q | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CACNA1C | c.4534A>G p.I1512V | Missense Mutation (SNP) | VAF 67/245 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- CFAP57 | c.759G>C p.E253D | Missense Mutation (SNP) | VAF 17/260 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- CILP2 | c.2870A>G p.N957S | Missense Mutation (SNP) | VAF 17/443 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.117); called by muse, mutect2
- COL3A1 | c.4193G>T p.G1398V | Missense Mutation (SNP) | VAF 115/481 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL6A5 | c.5975A>T p.N1992I (on ENST00000312481; = p.N1988I on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/566 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); called by muse, mutect2
- CYP4F22 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 242/543 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DBH | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 225/711 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- DENND4B | c.296A>G p.K99R | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DIP2B | c.1551+1G>T p.X517_splice | Splice Site (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- DPP4 | c.471G>T p.W157C | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EBF2 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- EBF3 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 29/349 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2
- EIF1AX | c.182T>A p.I61N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAP | c.2280C>A p.D760E | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FBXO2 | c.733A>C p.S245R | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- FCGBP | c.12585A>C p.R4195S | Missense Mutation (SNP) | VAF 42/578 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.257); called by muse, mutect2
- GATA4 | c.838A>G p.T280A | Missense Mutation (SNP) | VAF 179/728 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- GIMAP2 | c.61_70del p.S21Efs*34 | Frame Shift Del (DEL) | VAF 126/413 reads (31%) | called by mutect2, pindel, varscan2
- HAS2 | c.582G>T p.M194I | Missense Mutation (SNP) | VAF 74/355 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- HERC1 | c.7356G>C p.Q2452H | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- HUWE1 | c.2825G>A p.C942Y | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- KCNB2 | c.581_582insA p.L195Pfs*35 | Frame Shift Ins (INS) | VAF 39/143 reads (27%) | called by mutect2, pindel, varscan2
- KLRD1 | c.101-19_101-3del | Splice Region (DEL) | VAF 22/92 reads (24%) | called by mutect2, varscan2
- KRTAP3-1 | c.281G>C p.C94S | Missense Mutation (SNP) | VAF 195/359 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LGALS16 | c.269A>T p.D90V | Missense Mutation (SNP) | VAF 156/439 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- LRRD1 | c.2470A>T p.T824S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- MAGEB6B | c.653A>T p.K218M | Missense Mutation (SNP) | VAF 80/292 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- NAV3 | c.1606A>T p.T536S | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB5 | c.173A>T p.E58V | Missense Mutation (SNP) | VAF 87/160 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PDGFRB | c.835C>G p.P279A | Missense Mutation (SNP) | VAF 128/421 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- POTEA | c.1339C>T p.Q447* (on ENST00000519951 / NM_001005365.2; = p.Q401* on NM_001002920.1) | Nonsense Mutation (SNP) | VAF 54/197 reads (27%) | called by muse, mutect2, varscan2
- PPIG | c.424G>C p.G142R | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RFX6 | c.2748C>G p.I916M | Missense Mutation (SNP) | VAF 95/336 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ROS1 | c.3755T>G p.F1252C | Missense Mutation (SNP) | VAF 13/264 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- RUNX1 | c.154G>T p.V52L (on ENST00000344691 / NM_001001890.3; = p.V79L on NM_001754.5) | Missense Mutation (SNP) | VAF 121/324 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SAMD14 | c.875C>G p.P292R (on ENST00000330175 / NM_001257359.2; = p.P320R on NM_174920.4) | Missense Mutation (SNP) | VAF 351/660 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- SAMD14 | c.362G>C p.R121P | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- SENP7 | c.1413A>T p.E471D | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.028); called by muse, mutect2
- SGO1 | c.1305G>C p.Q435H (on ENST00000263753 / NM_001012410.5; = p.Q166H on NM_138484.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- SLC25A17 | c.420C>A p.D140E | Missense Mutation (SNP) | VAF 61/286 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SLC5A3 | c.1892A>T p.Y631F | Missense Mutation (SNP) | VAF 72/243 reads (30%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- TG | c.2126A>C p.E709A | Missense Mutation (SNP) | VAF 48/906 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.411); called by muse, mutect2
- TMEM270 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- TSR3 | c.923A>C p.K308T | Missense Mutation (SNP) | VAF 127/365 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- TTN | c.20221G>A p.G6741S (on ENST00000591111; = p.G5814S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/318 reads (7%) | PolyPhen benign (0.015); called by muse, mutect2
- TTYH1 | c.563G>C p.G188A | Missense Mutation (SNP) | VAF 86/254 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP6 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 120/233 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ZBTB7B | c.862dup p.Y288Lfs*20 (on ENST00000292176; = p.Y322Lfs*20 on NM_001252406.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 118/403 reads (29%) | called by mutect2, pindel, varscan2
- ZEB2 | c.1085C>A p.T362N | Missense Mutation (SNP) | VAF 77/289 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF629 | c.1417C>G p.L473V | Missense Mutation (SNP) | VAF 135/536 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AKAP3 | c.1581G>C p.L527= | Silent (SNP) | VAF 46/226 reads (20%) | called by muse, mutect2, varscan2
- ALDH5A1 | c.543C>A p.T181= | Silent (SNP) | VAF 106/380 reads (28%) | catalogued as COSV62373095; called by muse, mutect2, varscan2
- ATG12 | c.117A>T p.A39= | Silent (SNP) | VAF 35/68 reads (51%) | called by muse, mutect2, varscan2
- C1orf127 | c.1488G>C p.R496= | Silent (SNP) | VAF 75/257 reads (29%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.645G>A p.L215= | Silent (SNP) | VAF 18/96 reads (19%) | called by muse, mutect2, varscan2
- CEP126 | c.2865A>G p.R955= | Silent (SNP) | VAF 47/91 reads (52%) | called by muse, mutect2, varscan2
- CHPF2 | c.2148C>G p.L716= | Silent (SNP) | VAF 67/236 reads (28%) | called by muse, mutect2, varscan2
- COPG1 | c.612T>C p.R204= | Silent (SNP) | VAF 23/532 reads (4%) | called by muse, mutect2
- DGKZ | c.3198C>A p.I1066= (on ENST00000454345 / NM_001105540.2; = p.I878= on NM_003646.4) | Silent (SNP) | VAF 62/154 reads (40%) | catalogued as COSV58992957; called by muse, mutect2, varscan2
- EOGT | c.447T>C p.R149= | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- FCER1A | c.471G>A p.E157= | Silent (SNP) | VAF 135/326 reads (41%) | called by muse, mutect2, varscan2
- HIVEP3 | c.3570G>T p.P1190= | Silent (SNP) | VAF 69/177 reads (39%) | catalogued as COSV56010487; called by mutect2, varscan2
- NCKAP5 | c.3105G>T p.G1035= | Silent (SNP) | VAF 59/167 reads (35%) | called by muse, mutect2, varscan2
- NUBP1 | c.400C>T p.L134= | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- PDS5B | c.2574G>A p.L858= | Silent (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- RAD50 | c.2274T>C p.N758= | Silent (SNP) | VAF 83/171 reads (49%) | catalogued as COSV54755826; called by muse, mutect2, varscan2
- RGMA | c.198C>T p.A66= | Silent (SNP) | VAF 20/340 reads (6%) | called by muse, mutect2
- SHROOM4 | c.1674C>T p.S558= | Silent (SNP) | VAF 192/834 reads (23%) | catalogued as rs1557255169; called by muse, mutect2, varscan2
- TRIM56 | c.1143A>G p.K381= | Silent (SNP) | VAF 27/109 reads (25%) | called by muse, mutect2, varscan2
- TUBA8 | c.1020C>T p.T340= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as rs752318107; called by muse, mutect2, varscan2
- ZNF471 | c.489A>G p.K163= | Silent (SNP) | VAF 27/100 reads (27%) | called by muse, mutect2, varscan2
- AC021218.1 | n.1008C>T | RNA (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- ATP1A3 | c.*53G>T | 3'UTR (SNP) | VAF 67/144 reads (47%) | called by mutect2, varscan2
- HTR7 | c.-5G>T | 5'UTR (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- IL10RA | c.*1404A>T | 3'UTR (SNP) | VAF 232/465 reads (50%) | called by muse, mutect2, varscan2
- KIF5A | c.2910-40G>A | Intron (SNP) | VAF 143/532 reads (27%) | catalogued as rs1015375642; called by muse, mutect2, varscan2
- MPP2 | c.-18G>A | 5'UTR (SNP) | VAF 9/164 reads (5%) | catalogued as rs934194540; called by muse, mutect2
- SCIMP | c.283+105T>A | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, varscan2
- SSPOP | n.14654C>T | RNA (SNP) | VAF 102/394 reads (26%) | called by muse, mutect2, varscan2
- TTC9C | c.-357C>T | 5'UTR (SNP) | VAF 39/127 reads (31%) | catalogued as rs1169192425; called by muse, mutect2, varscan2
- USP34 | chr2:61186495 del AAGGTATGTTACTAATTACTGCCCTTCATATTA | 3'Flank (DEL) | VAF 11/110 reads (10%) | called by mutect2, pindel
